Somatic mutation profile of tumor specimen MMRF_2128_1_BM_CD138pos (aliquot MMRF_2128_1_BM_CD138pos_T1_KHS5U_L08154) from MMRF case MMRF_2128, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.3 years (24,231 days).
Specimen MMRF_2128_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3a307c6-d20b-4c76-9ee1-7510e740f573.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2128_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2128_1_PB_Whole_C2_KHS5U_L08155; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c81e89ca-89b3-482e-8e35-2fb446a2b968

The open-access MAF lists 96 somatic variants for this specimen: 45 protein-altering or splice-affecting, 11 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 25, Silent 11, Intron 8, 3'Flank 4, Nonsense Mutation 4, RNA 2, Frame Shift Del 2, 5'UTR 1, In Frame Ins 1, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5438A>G p.E1813G | Missense Mutation (SNP) | VAF 79/258 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58615258, COSV58615306, COSV58615741; called by muse, mutect2, varscan2
- ADCY5 | c.3623G>A p.R1208H | Missense Mutation (SNP) | VAF 85/362 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1064797295; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPN8 | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 47/102 reads (46%) | catalogued as rs908506815; called by muse, mutect2, varscan2
- CCDC168 | c.14005C>G p.L4669V | Missense Mutation (SNP) | VAF 29/351 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.3); catalogued as rs1439694805; called by muse, mutect2
- DDX53 | c.933C>A p.H311Q | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs967302685, COSV60068541; called by muse, mutect2
- DUSP16 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 95/210 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs946846822, COSV53808594; called by muse, mutect2, varscan2
- FAM155A | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 8/215 reads (4%) | catalogued as rs1245770175; called by muse, mutect2
- IGHD6-13 | c.2G>A p.G1E | Missense Mutation (SNP) | VAF 69/72 reads (96%) | catalogued as rs782195453; called by muse, mutect2, varscan2
- IGLV3-1 | c.133A>C p.K45Q | Missense Mutation (SNP) | VAF 67/75 reads (89%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs187892119; called by muse, mutect2, varscan2
- KRT31 | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 50/112 reads (45%) | catalogued as rs1004586037, COSV52435342; called by muse, mutect2, varscan2
- NOC3L | c.1129A>T p.I377L | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs1412802760; called by muse, mutect2, varscan2
- NRG1 | c.704C>T p.A235V (on ENST00000405005 / NM_013964.5; = p.A240V on NM_013956.5) | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs765166442, COSV55167212, COSV55179906; called by muse, mutect2, varscan2
- PHKA1 | c.1381T>G p.Y461D | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1031164358; called by muse, mutect2, varscan2
- PRPS2 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs752956171, COSV66179822, COSV66180377; called by muse, mutect2, varscan2
- PSMG4 | c.371A>G p.*124Wext*9 | Nonstop Mutation (SNP) | VAF 126/462 reads (27%) | catalogued as rs1187423740; called by muse, mutect2, varscan2
- RASEF | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs763531752; called by muse, mutect2, varscan2
- RNF34 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.46); catalogued as rs1555282529; called by muse, mutect2, varscan2
- SLITRK4 | c.1240A>C p.T414P | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV62025228; called by muse, mutect2, varscan2
- SV2B | c.1192T>G p.F398V | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs1459249379; called by muse, mutect2, varscan2
- TMEM132D | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs766949843, COSV101399809; called by muse, mutect2, varscan2
- ZNF385A | c.1046G>A p.R349H (on ENST00000338010 / NM_001130967.3; = p.R329H on NM_015481.3) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs760571183; called by muse, mutect2, varscan2
- BBX | c.1338G>T p.K446N | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2
- CLSTN1 | c.2575A>C p.T859P (on ENST00000377298 / NM_001009566.3; = p.T849P on NM_014944.4) | Missense Mutation (SNP) | VAF 148/287 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- COL6A3 | c.118_124del p.I40Ffs*2 | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | called by mutect2, pindel, varscan2
- DOCK7 | c.2447C>T p.A816V | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- EPHB2 | c.881G>C p.R294P | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLB1 | c.679T>C p.F227L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HLA-E | c.717G>C p.Q239H | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2
- ITGA6 | c.1277T>G p.I426S (on ENST00000442250; = p.I387S on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- JCHAIN | c.61A>G p.K21E | Missense Mutation (SNP) | VAF 113/226 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- KRTAP6-3 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 74/237 reads (31%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LTBP3 | c.2893+4A>G | Splice Region (SNP) | VAF 99/204 reads (49%) | called by muse, mutect2, varscan2
- NLRP14 | c.3155A>G p.K1052R | Missense Mutation (SNP) | VAF 112/273 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- OLFML2B | c.1478G>A p.R493K | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- PCDHGA1 | c.2275_2282dup p.D762Sfs*10 | Frame Shift Ins (INS) | VAF 18/82 reads (22%) | called by mutect2, varscan2
- PKD1L3 | c.2669C>A p.S890* | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- PLAA | c.1810A>T p.N604Y | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- RHOG | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 190/441 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEC24D | c.522_524dup p.P175dup | In Frame Ins (INS) | VAF 28/112 reads (25%) | called by mutect2, varscan2
- SIAE | c.381del p.S127Rfs*5 | Frame Shift Del (DEL) | VAF 140/961 reads (15%) | called by mutect2, pindel, varscan2
- SND1 | c.620T>A p.V207E | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- TIMM8A | c.163T>A p.L55M | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- TOP3B | c.1364T>G p.V455G | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); called by muse, mutect2
- ZNF552 | c.770A>C p.N257T | Missense Mutation (SNP) | VAF 74/333 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- ZNF727 | c.26T>G p.V9G | Missense Mutation (SNP) | VAF 71/160 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- AHNAK2 | c.8586C>T p.R2862= | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as COSV60906556; called by muse, mutect2, varscan2
- H3C11 | c.180G>A p.E60= | Silent (SNP) | VAF 99/218 reads (45%) | catalogued as rs373244072; called by muse, mutect2, varscan2
- HMCN2 | c.8934G>A p.T2978= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs1053467946; called by muse, mutect2, varscan2
- IGHD6-13 | c.3G>C p.G1= | Silent (SNP) | VAF 64/67 reads (96%) | catalogued as rs782246656; called by muse, mutect2, varscan2
- LELP1 | c.6G>A p.S2= | Silent (SNP) | VAF 35/346 reads (10%) | catalogued as rs771068500, COSV64202288; called by muse, mutect2, varscan2
- OCA2 | c.987C>G p.T329= | Silent (SNP) | VAF 34/199 reads (17%) | called by muse, mutect2, varscan2
- OR1J1 | c.168C>T p.H56= | Silent (SNP) | VAF 55/71 reads (77%) | catalogued as rs1247902341; called by muse, mutect2, varscan2
- RPS6KA2 | c.1551C>G p.T517= | Silent (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- SHROOM1 | c.1536C>A p.G512= | Silent (SNP) | VAF 34/168 reads (20%) | called by muse, mutect2, varscan2
- SLITRK4 | c.1239T>A p.I413= | Silent (SNP) | VAF 70/186 reads (38%) | called by muse, mutect2, varscan2
- WDFY3 | c.10506G>T p.P3502= | Silent (SNP) | VAF 94/278 reads (34%) | catalogued as COSV55707828; called by muse, mutect2, varscan2
- AC027612.1 | n.2323A>G | RNA (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- ADAMTSL4 | chr1:150561316 C>T | 3'Flank (SNP) | VAF 36/132 reads (27%) | catalogued as rs1448398964; called by muse, mutect2, varscan2
- BTF3 | c.574+183T>G | Intron (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2
- C1orf109 | c.*646G>A | 3'UTR (SNP) | VAF 22/99 reads (22%) | called by muse, mutect2, varscan2
- C8orf82 | c.*1369G>T | 3'UTR (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- CPED1 | c.*325C>A | 3'UTR (SNP) | VAF 22/81 reads (27%) | called by muse, mutect2, varscan2
- DKK2 | c.*971G>T | 3'UTR (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- ELFN2 | c.*861C>A | 3'UTR (SNP) | VAF 6/79 reads (8%) | catalogued as COSV68746168; called by muse, mutect2
- FAM110B | c.*635T>A | 3'UTR (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2, varscan2
- FBXO21 | c.1696+444C>G | Intron (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- FLJ42393 | n.1899T>C | RNA (SNP) | VAF 18/360 reads (5%) | called by muse, mutect2
- FMN1 | c.*226T>C | 3'UTR (SNP) | VAF 46/245 reads (19%) | called by muse, mutect2, varscan2
- FMNL3 | c.*2786C>T | 3'UTR (SNP) | VAF 11/284 reads (4%) | catalogued as rs1260598347; called by muse, mutect2
- FUBP1 | c.*1163A>C | 3'UTR (SNP) | VAF 41/86 reads (48%) | called by muse, mutect2, varscan2
- GAB1 | chr4:143471993 G>A | 3'Flank (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- HIGD2A | c.*203T>C | 3'UTR (SNP) | VAF 24/58 reads (41%) | catalogued as rs959097971; called by muse, mutect2, varscan2
- HSDL1 | c.220+115T>G | Intron (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2
- INHBA | c.*4115T>C | 3'UTR (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- KCNJ9 | c.*78A>T | 3'UTR (SNP) | VAF 4/36 reads (11%) | catalogued as rs1289820529, COSV58758158; called by muse, mutect2
- KCTD17 | c.*421A>G | 3'UTR (SNP) | VAF 43/85 reads (51%) | called by muse, mutect2, varscan2
- MARCHF8 | c.242+399T>G | Intron (SNP) | VAF 50/195 reads (26%) | called by muse, mutect2, varscan2
- MCOLN2 | c.*932C>T | 3'UTR (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- MMP16 | c.*1481G>T | 3'UTR (SNP) | VAF 33/106 reads (31%) | called by muse, mutect2, varscan2
- Metazoa_SRP | chr15:62244175 C>A | 3'Flank (SNP) | VAF 36/162 reads (22%) | called by muse, mutect2, varscan2
- NAP1L3 | c.*354_*357del | 3'UTR (DEL) | VAF 9/102 reads (9%) | called by mutect2, pindel
- PLPPR5 | c.*2269A>G | 3'UTR (SNP) | VAF 65/117 reads (56%) | catalogued as rs1271085550; called by muse, mutect2, varscan2
- PREX2 | c.*4872G>A | 3'UTR (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- RASEF | c.431+6873G>A | Intron (SNP) | VAF 63/314 reads (20%) | called by muse, mutect2, varscan2
- SLC6A15 | c.756+2896G>A | Intron (SNP) | VAF 26/68 reads (38%) | called by muse, varscan2
- SLC6A15 | c.756+2819_756+2820insG | Intron (INS) | VAF 25/81 reads (31%) | called by pindel, varscan2
- SLITRK4 | chrX:143627247 A>C | 3'Flank (SNP) | VAF 39/114 reads (34%) | called by muse, mutect2, varscan2
- TFCP2L1 | c.*613G>A | 3'UTR (SNP) | VAF 39/114 reads (34%) | catalogued as rs763366355; called by muse, mutect2, varscan2
- TM2D3 | c.*26T>A | 3'UTR (SNP) | VAF 47/138 reads (34%) | called by muse, mutect2, varscan2
- TMEM117 | c.*1030dup | 3'UTR (INS) | VAF 5/26 reads (19%) | called by mutect2, varscan2
- UHMK1 | c.*2332T>C | 3'UTR (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- UTP15 | c.*1477C>T | 3'UTR (SNP) | VAF 7/56 reads (13%) | catalogued as rs961777289; called by muse, mutect2, varscan2
- WIPI2 | c.*2039G>A | 3'UTR (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- WNT3A | c.*1331G>T | 3'UTR (SNP) | VAF 10/216 reads (5%) | called by muse, mutect2
- XKR6 | c.764+75928dup | Intron (INS) | VAF 27/71 reads (38%) | catalogued as rs1049667888; called by mutect2, pindel, varscan2
- YOD1 | c.-8T>C | 5'UTR (SNP) | VAF 60/147 reads (41%) | called by muse, mutect2, varscan2
